Surgical pathology report (de-identified scan), TCGA case TCGA-TQ-A7RS, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site University of Sao Paulo, specimen TCGA-TQ-A7RS-01A (Primary Tumor).

ICD-O-3
Oligodendroglioma, grade II
945013

ASCF

Site Brain, supratentorial NOS
C71.0
Brain, frontal lobe
C71.1

JW 10/4/13

Nature of material: Brain

Received on:

Macroscopy:

Received in formalin, irregular fragments of brain parenchyma measuring 4.5 x 3.5 x 3.0 cm. The surface shows well defined gyri and sulci, covered by delicate and congested leptomeningeal. To cuts, it is note softened and whitish tissue area. Note: Material fully included for histological analysis.

Microscopy:

Histological sections stained with H & E show lesion of neoplastic glial phenotype, consisting of relatively monomorphic cells with round nuclei, slightly hyperchromatic and often surrounded by a clear halo. The lesion exhibits rich vascular network support, formed by thin and branched capillaries. Displays also several areas with dystrophic calcifications. The lesion is infiltrative, involving cortex and white matter. In cortical areas, there is often neuronal satellitosis and subpial accumulation of neoplastic cells. It was not observed mitotic figures, foci of necrosis, marked atypia or vessels with multistrata endothelium.

Diagnosis:

Surgical resection product of left frontal brain lesion:

- Oligodendroglioma (grade II, according to the classification of OMS, 2007).

Award of 1p/19q deletion analysis:

The hybridizations were performed on 5 micrometers thick sections of formalin-fixed and paraffin-embedded neoplastic tissue (FFPE) in the most representative tumor area with 1p36/1q25 and 19q13/19p13 probe. 100 to 200 were evaluated in each slide cores.

In this case: The ratio of signals from 1p/1q probes was 0,82. The ratio of signals from 19q/19p probes was 0,64. Conclusion: Diffuse oligodendroglioma grade II WHO, with isolated codeletion 19q.

PROFESSIONAL PARTICIPANTS OF REPORT

IHBAA Discrepancy		☒

Source: NCI Genomic Data Commons file 10e09e53-1d1e-4377-9cde-9b45c01453f7 (TCGA-TQ-A7RS.90135819-8DF8-4410-BC80-816551A3AE46.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).